Gene-level copy-number profile of tumor specimen TCGA-04-1332-01A from TCGA case TCGA-04-1332, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.6 years (25,786 days).
Specimen TCGA-04-1332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.79e63073-7d6d-456b-92c7-a3a7f0216ee7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1332-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8ca8563d-2698-4e58-9c56-4347b3da3359

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,161; copy number 2: 15,953; copy number 3: 27,990; copy number 4: 9,218; copy number 5: 1,073; copy number 6: 591; copy number 7: 45; copy number 8: 114; copy number 9: 14; copy number 10: 166; copy number 11: 179; copy number 13: 62; copy number 14: 207; copy number 15: 28; copy number 19: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1332-01): tumor purity 0.5, ploidy 2.76, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 827 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,626,015–40,520,158, 79 genes, copy number 8 (broad region; genes not listed).
- chr14:18,333,726–23,435,660, 393 genes, copy number 8–14 (broad region; genes not listed).
- chr18:23,134,564–28,177,946, 87 genes, copy number 7–19 (within-gene range 2–19) (broad region; genes not listed).
- chr19:27,638,483–28,792,871, 27 genes, copy number 7: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1.
- chr19:36,534,774–41,096,195, 225 genes, copy number 11–13 (within-gene range 5–13) (broad region; genes not listed).
- chr19:43,353,686–43,614,498, 16 genes, copy number 13 (within-gene range 4–13): CD177, AC005392.3, CD177P1, TEX101, LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5.

Autosomal genes at a single copy (total copy number 1): 4,161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
